Somatic mutation profile of tumor specimen 0DK5H9 from CCDI case PBBXRU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 4.4 years (1,624 days).
Specimen 0DK5H9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f9669424-a3fc-41cd-9825-a00c4b20c9fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DK5HO (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8de8e8fe-5813-465f-82eb-c10a09e1ce0e

The open-access MAF lists 53 somatic variants for this specimen: 30 protein-altering or splice-affecting, 14 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 14, Intron 5, 3'UTR 3, Splice Site 3, Frame Shift Del 2, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRL3 | c.269G>A p.R90H (on ENST00000506720 / NM_001322402.2; = p.R22H on NM_015236.6) | Missense Mutation (SNP) | VAF 85/894 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772186652, COSV72268570; called by muse, mutect2
- CACNA1C | c.1523G>A p.R508Q | Missense Mutation (SNP) | VAF 96/509 reads (19%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.945); catalogued as rs762091177, COSV59753261; called by muse, mutect2, varscan2
- CFAP100 | c.530C>T p.T177M | Missense Mutation (SNP) | VAF 101/523 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs142359829; called by muse, mutect2, varscan2
- CUBN | c.4351-1G>T p.X1451_splice | Splice Site (SNP) | VAF 64/1554 reads (4%) | catalogued as COSV100912592; called by muse, mutect2
- HAS1 | c.1274C>T p.A425V | Missense Mutation (SNP) | VAF 166/211 reads (79%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs777058982, COSV55788668; called by muse, mutect2, varscan2
- IVD | c.724C>G p.P242A | Missense Mutation (SNP) | VAF 203/637 reads (32%) | PolyPhen possibly damaging (0.737); catalogued as rs923700627; called by muse, mutect2, varscan2
- KIAA1586 | c.2202G>A p.M734I | Missense Mutation (SNP) | VAF 89/641 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.053); catalogued as COSV104425729; called by muse, mutect2, varscan2
- MMRN1 | c.1409T>C p.M470T | Missense Mutation (SNP) | VAF 284/440 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.518); catalogued as rs1264660443; called by muse, mutect2
- OR4A15 | c.829A>G p.T277A | Missense Mutation (SNP) | VAF 272/852 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.941); catalogued as rs141071031, COSV59037637; called by muse, mutect2, varscan2
- PITPNM1 | c.691G>A p.D231N | Missense Mutation (SNP) | VAF 106/1308 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62709512; called by muse, mutect2
- POTEE | c.215G>T p.C72F | Missense Mutation (SNP) | VAF 52/213 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.308); catalogued as COSV100387763; called by muse, mutect2, varscan2
- PSKH1 | c.1144C>T p.R382C | Missense Mutation (SNP) | VAF 60/196 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.644); catalogued as rs201909376; called by muse, mutect2, varscan2
- ROBO2 | c.3535G>T p.D1179Y | Missense Mutation (SNP) | VAF 215/650 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1317771705, COSV59943283; called by muse, mutect2, varscan2
- RPS6KA2 | c.1385G>A p.R462Q | Missense Mutation (SNP) | VAF 109/655 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.952); catalogued as rs1403549805; called by muse, mutect2, varscan2
- SLC16A14 | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 153/802 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as rs772190928; called by muse, mutect2, varscan2
- ARHGAP1 | c.317+1del p.X106_splice | Splice Site (DEL) | VAF 237/711 reads (33%) | called by mutect2, pindel, varscan2
- ARHGEF9 | c.541G>T p.G181* | Nonsense Mutation (SNP) | VAF 24/377 reads (6%) | called by muse, mutect2
- ARL4D | c.515A>G p.D172G | Missense Mutation (SNP) | VAF 229/553 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- BSX | c.277G>C p.A93P | Missense Mutation (SNP) | VAF 156/1509 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CROCC | c.1312C>G p.Q438E | Missense Mutation (SNP) | VAF 65/606 reads (11%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- KIRREL1 | c.1491C>G p.I497M | Missense Mutation (SNP) | VAF 47/425 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- MPPE1 | c.389_390+11del p.X130_splice | Splice Site (DEL) | VAF 46/421 reads (11%) | called by mutect2, pindel, varscan2
- PIK3C3 | c.2334G>T p.K778N | Missense Mutation (SNP) | VAF 320/982 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RNF17 | c.969T>G p.N323K | Missense Mutation (SNP) | VAF 66/754 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.084); called by muse, mutect2
- SPTBN1 | c.781C>G p.P261A | Missense Mutation (SNP) | VAF 212/793 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- SPX | c.180_183del p.K61Tfs*18 | Frame Shift Del (DEL) | VAF 69/516 reads (13%) | called by mutect2, pindel, varscan2
- TENM4 | c.7345C>G p.L2449V | Missense Mutation (SNP) | VAF 91/1392 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.192); called by muse, mutect2
- TPRG1 | c.416_438del p.P139Lfs*21 | Frame Shift Del (DEL) | VAF 98/945 reads (10%) | called by mutect2, pindel
- ZNF717 | c.908A>C p.K303T | Missense Mutation (SNP) | VAF 57/498 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.514); called by muse, varscan2
- ZNF780A | c.641T>G p.F214C | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- AGL | c.669T>G p.A223= | Silent (SNP) | VAF 213/555 reads (38%) | called by muse, mutect2, varscan2
- CCSER2 | c.1308C>G p.L436= | Silent (SNP) | VAF 101/418 reads (24%) | called by muse, mutect2, varscan2
- CNTF | c.144C>T p.I48= | Silent (SNP) | VAF 222/773 reads (29%) | called by muse, mutect2, varscan2
- GPR61 | c.486G>C p.V162= | Silent (SNP) | VAF 12/404 reads (3%) | called by muse, mutect2
- HMCN1 | c.10560C>T p.I3520= | Silent (SNP) | VAF 247/573 reads (43%) | catalogued as rs1193193125, COSV54891968; called by muse, mutect2, varscan2
- IL5RA | c.102C>A p.V34= | Silent (SNP) | VAF 57/837 reads (7%) | called by muse, mutect2
- KRT1 | c.1530C>T p.T510= | Silent (SNP) | VAF 210/504 reads (42%) | called by muse, mutect2, varscan2
- MROH2B | c.3204G>A p.Q1068= | Silent (SNP) | VAF 309/863 reads (36%) | called by muse, mutect2, varscan2
- OR8B2 | c.582C>G p.V194= | Silent (SNP) | VAF 87/2602 reads (3%) | called by muse, mutect2
- PARP2 | c.1542C>T p.S514= | Silent (SNP) | VAF 63/614 reads (10%) | catalogued as COSV51638186; called by muse, mutect2, varscan2
- PKHD1L1 | c.1710A>C p.S570= | Silent (SNP) | VAF 64/757 reads (8%) | called by muse, mutect2
- SPTBN1 | c.2094C>T p.I698= | Silent (SNP) | VAF 230/807 reads (29%) | called by muse, mutect2, varscan2
- TLR10 | c.168C>T p.S56= | Silent (SNP) | VAF 110/960 reads (11%) | catalogued as rs1330477802; called by muse, mutect2, varscan2
- TTN | c.86130T>C p.D28710= (on ENST00000591111; = p.D21286= on NM_003319.4) | Silent (SNP) | VAF 384/1259 reads (31%) | catalogued as rs769390930; ClinVar: likely benign; called by muse, mutect2
- AVPR1A | c.*11C>A | 3'UTR (SNP) | VAF 222/515 reads (43%) | called by muse, mutect2, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 10/274 reads (4%) | called by muse, mutect2
- CD86 | c.64+59C>A | Intron (SNP) | VAF 80/383 reads (21%) | catalogued as rs1337127325; called by mutect2, varscan2
- GPR25 | c.-21C>T | 5'UTR (SNP) | VAF 24/128 reads (19%) | catalogued as rs1386465524; called by muse, mutect2, varscan2
- LAPTM5 | c.181+12G>A | Intron (SNP) | VAF 88/424 reads (21%) | called by muse, mutect2
- PDLIM7 | c.572+471C>T | Intron (SNP) | VAF 30/71 reads (42%) | catalogued as rs963213639; called by muse, mutect2
- RGSL1 | c.2934-32C>A | Intron (SNP) | VAF 146/363 reads (40%) | called by muse, mutect2, varscan2
- TMEM250 | c.*85G>A | 3'UTR (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
- XIRP2 | c.*442A>C | 3'UTR (SNP) | VAF 250/1024 reads (24%) | called by muse, mutect2, varscan2
